Somatic mutation profile of tumor specimen 0DAGP0 from CCDI case PBBJYH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 19.1 years (6,973 days).
Specimen 0DAGP0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12bc3dab-cd4b-4152-8f06-fa847625b701.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DAGOT (Solid Tissue; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a93d5d8-b4af-438a-b97b-38d6079bfb38

The open-access MAF lists 35 somatic variants for this specimen: 27 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 5, Frame Shift Del 2, Intron 2, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR1 | c.1966A>G p.K656E (on ENST00000447712 / NM_023110.3; = p.K654E on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 400/639 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs869320694, COSV58327161, COSV58340654; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ALDH1A2 | c.1289C>A p.T430K | Missense Mutation (SNP) | VAF 94/297 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.035); catalogued as COSV51089223; called by muse, mutect2, varscan2
- APCDD1 | c.1449C>A p.S483R | Missense Mutation (SNP) | VAF 95/223 reads (43%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV62372859; called by muse, mutect2, varscan2
- ARFGAP2 | c.251G>T p.G84V | Missense Mutation (SNP) | VAF 93/203 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV54067925; called by mutect2, varscan2
- CCDC85C | c.593G>A p.G198E | Missense Mutation (SNP) | VAF 52/99 reads (53%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.862); catalogued as rs1269823995; called by muse, mutect2, varscan2
- CCK | c.238G>A p.V80I | Missense Mutation (SNP) | VAF 188/441 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs377413820; called by muse, mutect2, varscan2
- COL6A3 | c.2804G>A p.R935Q | Missense Mutation (SNP) | VAF 69/176 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762016120, COSV55112550; called by muse, mutect2, varscan2
- HDC | c.963del p.K321Nfs*10 | Frame Shift Del (DEL) | VAF 94/203 reads (46%) | catalogued as COSV51068307; called by mutect2, varscan2
- KIF7 | c.1219G>T p.A407S | Missense Mutation (SNP) | VAF 120/256 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.158); catalogued as rs1457777027; called by muse, mutect2, varscan2
- PPP3CB | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 54/133 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as COSV60443374; called by muse, mutect2, varscan2
- SERPINB10 | c.448A>G p.I150V | Missense Mutation (SNP) | VAF 102/248 reads (41%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as COSV53074951; called by muse, mutect2, varscan2
- SLC12A5 | c.2638C>T p.R880C (on ENST00000454036 / NM_001134771.2; = p.R857C on NM_020708.5) | Missense Mutation (SNP) | VAF 144/316 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs764947617, COSV99715855; called by muse, mutect2, varscan2
- TENM4 | c.7125G>C p.L2375F | Missense Mutation (SNP) | VAF 165/398 reads (41%) | SIFT tolerated (0.56); PolyPhen benign (0.348); catalogued as COSV53642819; called by muse, mutect2, varscan2
- U2SURP | c.2858G>A p.R953Q | Missense Mutation (SNP) | VAF 151/345 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs779031489; called by muse, mutect2, varscan2
- USP54 | c.1448G>A p.G483E | Missense Mutation (SNP) | VAF 55/123 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs761600145; called by muse, mutect2, varscan2
- WDR46 | c.1292A>G p.K431R | Missense Mutation (SNP) | VAF 63/129 reads (49%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as rs772260654; called by muse, mutect2, varscan2
- ATRX | c.6557C>T p.S2186F | Missense Mutation (SNP) | VAF 87/96 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ATRX | c.6556T>G p.S2186A | Missense Mutation (SNP) | VAF 89/98 reads (91%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- CACNA1H | c.5245-2A>C p.X1749_splice | Splice Site (SNP) | VAF 69/154 reads (45%) | called by muse, mutect2, varscan2
- EFCAB7 | c.1771G>A p.G591R | Missense Mutation (SNP) | VAF 112/251 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2
- GLI1 | c.2822C>T p.A941V | Missense Mutation (SNP) | VAF 90/2725 reads (3%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); called by muse, mutect2
- KMT2E | c.2337del p.Y779* | Frame Shift Del (DEL) | VAF 86/198 reads (43%) | called by mutect2, varscan2
- LIMK1 | c.908C>T p.P303L | Missense Mutation (SNP) | VAF 128/311 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- OR4N2 | c.178T>C p.Y60H | Missense Mutation (SNP) | VAF 157/605 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TEX13C | c.1928C>G p.P643R | Missense Mutation (SNP) | VAF 208/254 reads (82%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- TKT | c.1711G>A p.A571T | Missense Mutation (SNP) | VAF 97/204 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZIC2 | c.1309C>A p.P437T | Missense Mutation (SNP) | VAF 65/197 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ARHGAP40 | c.1032C>T p.D344= | Silent (SNP) | VAF 205/430 reads (48%) | catalogued as rs370709098; called by muse, mutect2, varscan2
- IFI16 | c.570A>G p.K190= | Silent (SNP) | VAF 54/139 reads (39%) | called by muse, varscan2
- IL27RA | c.259C>A p.R87= | Silent (SNP) | VAF 130/303 reads (43%) | called by muse, mutect2, varscan2
- MYT1 | c.2655G>A p.K885= | Silent (SNP) | VAF 116/263 reads (44%) | called by muse, mutect2, varscan2
- PCDHA7 | c.1662C>T p.F554= | Silent (SNP) | VAF 79/187 reads (42%) | catalogued as rs781932623, COSV65347498; called by muse, mutect2, varscan2
- DCTN2 | c.925-60C>G | Intron (SNP) | VAF 44/1269 reads (3%) | called by muse, mutect2
- MRPS2 | c.44-57del | Intron (DEL) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- PHKB | c.-5G>A | 5'UTR (SNP) | VAF 65/171 reads (38%) | catalogued as rs1266044380; called by muse, mutect2
